Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LD-01A (Primary Tumor).

[page 1 of 2]
TSS Name/#:

1CD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, right tube and ovary
- 2: SP: Myoma, lt. tube ovary
- 3: SP: Rt. para-aortic lymph nodes
- 4: SP: Lt. para-aortic lymph nodes
- 5: SP: Lt. external iliac lymph nodes
- 6: SP: Lt. obturator lymph nodes
- 7: SP: Lt. hypogastric lymph nodes
- 8: SP: Lt. common iliac lymph nodes
- 9: SP: Rt. external iliac lymph nodes
- 10: SP: Rt. hypogastric lymph nodes
- 11: SP: Rt. common iliac lymph nodes
- 12: SP: Rt. obturator lymph nodes

Adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1

lw
5/11

DIAGNOSIS:

- 1) UTERUS, LEFT FALLOPIAN TUBE AND OVARY; EXCISION:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS.
- FIGO GRADE III (> 50% SOLID GROWTH), NUCLEAR GRADE 2.
- THE TUMOR INVADDES TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 20 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 23 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- EXTENSIVE VASCULAR INVASION IS PRESENT.
- THE ENDOMETRIUM SHOWS ATROPHY.
- THE MYOMETRIUM SHOWS LEIOMYOMAS.
- ALL ADNEXIAE ARE UNREMARKABLE.
- 2) SOFT TISSUE, OVARY, FALLOPIAN TUBE, LEFT; EXCISION:
- UNREMARKABLE OVARY AND LEIOMYOMA (4.0 CM).
- BENIGN FALLOPIAN TUBE.
- 3) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).
- 4) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).
- 5) LYMPH NODE, LEFT EXTERNAL ILIAC; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)

** Continued on next page **

[page 2 of 2]
- 6) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- NINE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/9).
- 7) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- 8) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).
- 9) LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).
- 10) LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).
- 11) "LYMPH NODES", RIGHT COMMON ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODE SEEN.
- 12) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 23b80294-7ce9-40dc-b812-f96e727084dd (TCGA-AP-A0LD.10B9E917-C1FB-480D-9DB2-8E93FA446ADC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).